Gene-level copy-number profile of tumor specimen TCGA-09-1673-01A from TCGA case TCGA-09-1673, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.9 years (18,599 days).
Specimen TCGA-09-1673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f7833173-18ff-44f8-97cb-148e73842517.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-1673-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff34b301-9115-4d50-9e69-9e7a684174df

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 18; copy number 2: 9,406; copy number 3: 13,212; copy number 4: 24,887; copy number 5: 2,877; copy number 6: 5,648; copy number 7: 1,082; copy number 8: 1,406; copy number 9: 474; copy number 10: 620; copy number 11: 124; copy number 12: 31; copy number 13: 14; copy number 14: 3; copy number 16: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-1673-01A-01D-0559-01): tumor purity 0.87, ploidy 4.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,273 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,915,871–9,088,478, 38 genes, copy number 9: TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1.
- chr1:150,363,091–150,780,644, 20 genes, copy number 10 (within-gene range 4–10): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1.
- chr2:64,330,481–65,056,168, 27 genes, copy number 10 (within-gene range 7–10): AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576.
- chr2:68,361,214–69,437,628, 23 genes, copy number 9: AC015969.1, PLEK, AC127383.1, FBXO48, APLF, AC130709.1, PROKR1, ARHGAP25, LINC01890, LINC01888, BMP10, GKN3P, GKN2, GKN1, ANTXR1, AC114802.1, MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1.
- chr3:14,348,451–15,455,940, 30 genes, copy number 10: LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53, COL6A4P1, CAPN7, SH3BP5-AS1, SH3BP5, RNU6-454P, HMGN2P7, METTL6, EAF1, RNU6-1024P, EAF1-AS1.
- chr3:32,190,747–36,170,448, 51 genes, copy number 10: RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1, RFC3P1.
- chr3:37,452,115–40,309,698, 67 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr3:64,092,236–65,193,509, 11 genes, copy number 11 (within-gene range 8–11): PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040.
- chr3:65,359,268–65,359,717, 1 gene, copy number 11: AC121493.1.
- chr3:97,759,523–97,975,056, 7 genes, copy number 10: AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1.
- chr3:168,249,522–170,454,733, 45 genes, copy number 11: EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11.
- chr3:170,459,548–170,586,075, 2 genes, copy number 11 (within-gene range 8–11): SLC7A14, KRT8P13.
- chr3:172,603,440–173,336,965, 12 genes, copy number 11 (within-gene range 6–11): SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:179,323,031–185,052,614, 145 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr5:92,889,387–92,939,591, 2 genes, copy number 10: CCT7P2, LINC02058.
- chr6:122,996,235–126,203,817, 22 genes, copy number 10–16 (within-gene range 6–16): CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11.
- chr6:127,909,833–130,574,112, 25 genes, copy number 10–13: MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA.
- chr7:19,918,981–24,445,128, 75 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr7:146,050,062–153,413,985, 166 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:63,136,223–63,234,911, 5 genes, copy number 9: AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P.
- chr8:109,240,919–110,105,964, 14 genes, copy number 9 (within-gene range 8–9): NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48.
- chr8:122,414,332–128,187,101, 120 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr10:1,177,313–1,737,525, 1 gene, copy number 10 (within-gene range 7–10): ADARB2.
- chr10:1,290,018–4,785,100, 51 genes, copy number 10: AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1.
- chr10:34,109,560–34,815,325, 1 gene, copy number 9 (within-gene range 6–14): PARD3.
- chr10:34,488,583–36,626,138, 37 genes, copy number 9–14: ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.
- chr12:31,627,575–31,731,204, 5 genes, copy number 10 (within-gene range 6–10): AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2.
- chr12:68,248,242–68,971,570, 27 genes, copy number 10: IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr13:60,396,457–60,613,734, 2 genes, copy number 10: TDRD3, RNA5SP31.
- chr13:60,636,888–60,638,097, 1 gene, copy number 10: EIF4A1P6.
- chr13:97,221,434–97,394,120, 1 gene, copy number 9 (within-gene range 3–9): MBNL2.
- chr13:97,362,972–100,530,437, 70 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr15:84,597,809–84,633,988, 2 genes, copy number 10 (within-gene range 8–10): AC048382.5, ZSCAN2.
- chr15:84,622,015–86,116,747, 47 genes, copy number 10: AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, AC012291.3, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1, LINC01584.
- chr15:86,138,269–86,173,270, 3 genes, copy number 10: RNA5SP400, AC016180.2, AC016180.1.
- chr19:15,226,919–16,496,167, 70 genes, copy number 10 (broad region; genes not listed).
- chr19:16,496,394–16,542,437, 2 genes, copy number 10: C19orf44, CHERP.
- chr20:47,352,561–47,656,877, 7 genes, copy number 10: AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1.
- chr20:47,677,901–47,686,297, 1 gene, copy number 10: AL354813.1.
- chr21:18,857,779–22,205,332, 35 genes, copy number 9: PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
